Somatic mutation profile of tumor specimen C3L-00614-59 (aliquot CPT0100860002) from CPTAC case C3L-00614, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 60.6 years (22,119 days).
Specimen C3L-00614-59: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bcb872e-1f9a-47c1-af83-15ebdaf2ab50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00614-51 (Buccal Cell Normal), aliquot CPT0100780003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ddd344e-ddcc-47fb-9d2b-dad8df0268e6

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 3, Silent 2, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 62/203 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDC27 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50367727; called by muse, mutect2, varscan2
- MYORG | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 76/151 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as rs1480161501; called by muse, mutect2, varscan2
- SSRP1 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 89/197 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs760925841; called by muse, mutect2, varscan2
- XIRP1 | c.4190C>T p.P1397L | Missense Mutation (SNP) | VAF 116/260 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs148173157; called by muse, mutect2, varscan2
- ACTN2 | c.141G>A p.W47* | Nonsense Mutation (SNP) | VAF 239/539 reads (44%) | called by muse, mutect2, varscan2
- KLHL23 | c.299T>C p.I100T | Missense Mutation (SNP) | VAF 77/154 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- CATSPER4 | c.159C>T p.Y53= | Silent (SNP) | VAF 64/229 reads (28%) | catalogued as rs750774174; called by muse, mutect2, varscan2
- PHYHD1 | c.576C>T p.G192= (on ENST00000372592 / NM_001100876.2; = p.A185V on NM_174933.4) | Silent (SNP) | VAF 118/275 reads (43%) | called by muse, mutect2, varscan2
- DNAJA4 | c.132+769C>T | Intron (SNP) | VAF 50/122 reads (41%) | catalogued as rs747603131; called by muse, mutect2
- ENAH | c.803-112C>T | Intron (SNP) | VAF 14/223 reads (6%) | called by muse, mutect2
- MIER3 | c.35-32T>G | Intron (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- RBBP4 | c.-68G>C | 5'UTR (SNP) | VAF 47/133 reads (35%) | catalogued as rs1268548689; called by muse, mutect2, varscan2
